Gene-level copy-number profile of specimen HCM-BROD-0871-C49-85M from HCMI case HCM-BROD-0871-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 60.7 years (22,167 days).
Specimen HCM-BROD-0871-C49-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 18.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2361ed76-594d-444a-9138-624b9d104af2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0871-C49-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,267 have no estimate.
https://portal.gdc.cancer.gov/files/8f3d08ee-4070-41a0-adde-a4f038f07dc8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 13,230; copy number 2: 42,352; copy number 3: 1,055; copy number 4: 871; copy number 5: 746; copy number 6: 53; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:49,444,374–50,125,720, 25 genes (within-gene range 0–1): SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr13:50,082,295–50,173,181, 5 genes (within-gene range 0–1): AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4.
- chr14:18,614,388–18,945,139, 18 genes: CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 800 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,269,604–153,032,900, 332 genes, copy number 5–6 (broad region; genes not listed).
- chr1:153,070,224–155,750,137, 162 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr1:168,695,468–171,824,959, 74 genes, copy number 5–6 (broad region; genes not listed).
- chr1:173,351,689–180,909,166, 136 genes, copy number 5–6 (broad region; genes not listed).
- chr1:205,302,063–205,943,460, 24 genes, copy number 5: NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT, CDK18, RNU2-19P, MFSD4A, RNU6-418P, ELK4, AC096533.1, SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, SLC41A1, AC119673.2, PM20D1, SLC26A9, AL713965.1.
- chr1:226,231,149–226,333,655, 3 genes, copy number 5: LIN9, YBX1P9, AL359742.1.
- chr1:226,411,615–226,412,135, 1 gene, copy number 7: AL359704.1.
- chr1:226,870,184–228,555,901, 68 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,886. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
